Gene-level copy-number profile of tumor specimen TCGA-VQ-A91X-01A from TCGA case TCGA-VQ-A91X, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 74.8 years (27,314 days).
Specimen TCGA-VQ-A91X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.42588bed-072e-4441-baec-f906b14dd740.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9ffd7ff7-7108-4c94-bf6a-1e825555936b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 5,237; copy number 3: 17,201; copy number 4: 20,793; copy number 5: 8,697; copy number 6: 3,972; copy number 7: 1,162; copy number 8: 1,326; copy number 9: 1,109; copy number 10: 147; copy number 11: 25; copy number 12: 4; copy number 14: 17; copy number 18: 7; copy number 24: 8; copy number 34: 20; copy number 57: 41; copy number 85: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91X-01A-12D-A40Z-01): tumor purity 0.53, ploidy 4.13, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,397 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:958,323–1,114,329, 4 genes, copy number 10: LINC01622, AL033381.2, AL033381.1, AL033381.3.
- chr6:47,368,943–47,627,263, 6 genes, copy number 10 (within-gene range 5–10): B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1.
- chr6:165,987,551–170,738,536, 124 genes, copy number 10 (broad region; genes not listed).
- chr10:3,433,508–6,625,346, 79 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr10:30,820,207–36,626,138, 93 genes, copy number 9 (broad region; genes not listed).
- chr10:55,247,755–55,746,908, 6 genes, copy number 10: AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1.
- chr16:4,777,606–5,235,822, 21 genes, copy number 11: SEPTIN12, AC020663.4, SMIM22, AC020663.2, ROGDI, GLYR1, AC020663.3, UBN1, PPL, SEC14L5, NAGPA-AS1, NAGPA, ALG1, C16orf89, AC026458.1, EEF2KMT, AC026458.2, AC074051.3, ENPP7P14, AC074051.1, LINC02164.
- chr16:5,260,686–5,366,688, 4 genes, copy number 11: AC074051.2, RPS3AP48, SNRPCP20, NPM1P3.
- chr16:20,854,925–21,214,510, 7 genes, copy number 10 (within-gene range 6–10): DCUN1D3, LYRM1, DNAH3, AC008551.1, TMEM159, AF001550.1, ZP2.
- chr16:75,228,181–75,286,800, 3 genes, copy number 12 (within-gene range 8–12): BCAR1, AC009078.3, RNU6-758P.
- chr16:75,321,890–75,325,048, 1 gene, copy number 12: AC009054.1.
- chr17:39,626,740–40,368,438, 41 genes, copy number 57: PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54.
- chr17:41,582,279–41,930,542, 19 genes, copy number 85: KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2.
- chr18:316,737–2,489,426, 38 genes, copy number 9 (within-gene range 4–9): COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3.
- chr19:27,902,595–30,085,893, 52 genes, copy number 14–34 (within-gene range 5–34): AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr20:30,214,765–64,313,132, 899 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
